Somatic mutation profile of tumor specimen TCGA-75-5147-01A (aliquot TCGA-75-5147-01A-01D-1625-08) from TCGA case TCGA-75-5147, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Bronchiolo-alveolar carcinoma, non-mucinous; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB.
Specimen TCGA-75-5147-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f679ab69-0fdc-4905-9086-01f4a6136df8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-75-5147-10A (Blood Derived Normal), aliquot TCGA-75-5147-10A-01D-1625-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31feb00f-ddca-48b4-a94a-0d465079a281

The open-access MAF lists 39 somatic variants for this specimen: 34 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 30, Silent 5, Frame Shift Ins 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 17/52 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.2222G>A p.G741E | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV60914725, COSV60916531; called by muse, mutect2, varscan2
- ABCG5 | c.1504T>G p.F502V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV53211504; called by muse, mutect2, varscan2
- ANK3 | c.2078G>T p.S693I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV55063838; called by muse, mutect2
- CCDC7 | c.2408A>G p.E803G | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.993); catalogued as COSV56544527; called by muse, mutect2
- CD244 | c.762G>C p.K254N (on ENST00000368033 / NM_001166663.2; = p.K249N on NM_016382.4) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV59239083; called by muse, mutect2, varscan2
- CDC42 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.097); catalogued as COSV59662513; called by muse, mutect2, varscan2
- CSMD3 | c.4440G>A p.M1480I (on ENST00000297405 / NM_001363185.1; = p.M1376I on NM_052900.3) | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (1); PolyPhen possibly damaging (0.696); catalogued as rs1399749170, COSV52214006, COSV99845191; called by muse, mutect2
- CST5 | c.266A>C p.K89T | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV59014714; called by muse, mutect2, varscan2
- DEF8 | c.955C>A p.R319S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV51918781, COSV51919634; called by muse, mutect2, varscan2
- DMD | c.5124G>C p.K1708N | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.323); catalogued as COSV63765135; called by muse, mutect2, varscan2
- FBXO24 | c.626C>T p.P209L (on ENST00000241071 / NM_033506.3; = p.P247L on NM_012172.5) | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs201493865, COSV53826900, COSV99575618; called by muse, mutect2, varscan2
- FOXN2 | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs751841139, COSV61318804; called by muse, mutect2
- GNL2 | c.1915C>A p.Q639K | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56170290; called by muse, mutect2, varscan2
- GOLGA3 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 89/326 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.16); catalogued as rs766679941, COSV52629481, COSV52648507; called by muse, mutect2, varscan2
- HNRNPH1 | c.706T>A p.Y236N | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.629); catalogued as COSV61486818; called by muse, mutect2, varscan2
- KDM4C | c.1557G>C p.E519D | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.236); catalogued as COSV67187846; called by muse, mutect2, varscan2
- OR51A7 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as rs868186752, COSV63788529; called by muse, mutect2, varscan2
- OR5AS1 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as rs370300707; called by muse, mutect2, varscan2
- PLXNA1 | c.3595dup p.L1199Pfs*77 | Frame Shift Ins (INS) | VAF 22/86 reads (26%) | catalogued as rs1300293856; called by mutect2, pindel, varscan2
- PON3 | c.613C>T p.L205F | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV55698883, COSV55699977; called by muse, mutect2
- SHANK2 | c.4717G>C p.D1573H | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV53603695, COSV99572583; called by muse, mutect2, varscan2
- SLC34A2 | c.1732_1733insAA p.R578Qfs*24 | Frame Shift Ins (INS) | VAF 33/123 reads (27%) | catalogued as COSV101158275; called by mutect2, pindel, varscan2
- SLC6A13 | c.605G>C p.G202A | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58257807; called by muse, mutect2
- SLITRK3 | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as COSV53849538; called by muse, mutect2, varscan2
- SMC4 | c.1592C>G p.S531C | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as COSV61005743; called by muse, mutect2, varscan2
- STOML1 | c.337T>G p.S113A | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.703); catalogued as COSV57551796; called by muse, mutect2, varscan2
- TAF1C | c.1706C>G p.A569G | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV58987268; called by muse, varscan2
- TRPC1 | c.926G>A p.R309H (on ENST00000476941 / NM_001251845.2; = p.R275H on NM_003304.4) | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs748271979, COSV56426460; called by muse, mutect2, varscan2
- TYK2 | c.317+1G>T p.X106_splice | Splice Site (SNP) | VAF 45/96 reads (47%) | catalogued as COSV53388435; called by muse, mutect2, varscan2
- UNK | c.1892C>G p.S631C | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV52884668; called by muse, mutect2, varscan2
- ZNF217 | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.167); catalogued as COSV100184302, COSV56598347; called by muse, mutect2
- ZNF484 | c.1271A>T p.K424M | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60258208; called by muse, mutect2, varscan2
- ARSI | c.1144del p.A382Pfs*46 | Frame Shift Del (DEL) | VAF 20/143 reads (14%) | called by mutect2, pindel, varscan2
- DYNC1I1 | c.1395C>T p.Y465= | Silent (SNP) | VAF 55/180 reads (31%) | catalogued as rs1249205447, COSV61463590; called by muse, mutect2, varscan2
- OR2D3 | c.297T>C p.V99= | Silent (SNP) | VAF 66/184 reads (36%) | catalogued as COSV58573260; called by muse, mutect2, varscan2
- PTPRF | c.5343G>A p.E1781= | Silent (SNP) | VAF 39/129 reads (30%) | catalogued as COSV63446025; called by muse, mutect2, varscan2
- SHOX2 | c.666T>C p.Y222= (on ENST00000441443 / NM_006884.3; = p.Y246= on NM_003030.4) | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as COSV67464084; called by muse, mutect2, varscan2
- SLC28A2 | c.441G>A p.T147= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs781420040, COSV61663801, COSV61664396; called by muse, mutect2, varscan2
